Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7248, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7248-01A (Primary Tumor).

[page 1 of 2]
Received: [REDACTED]

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) RIGHT PYRIFORM:
Squamous mucosa with mild atypia.
- (B) EPIGLOTTIS:
INVASIVE SQUAMOUS CARCINOMA, GRADE 2.
- (C) RIGHT EJ VEIN NODE:
Lymph node, no tumor.
- (D) RIGHT JUGULAR BRANCH:
SQUAMOUS CARCINOMA IN FIBROCONNECTIVE TISSUE.
- (E) LEFT SPINAL ACCESSORY NODE:
Two lymph nodes, no tumor.
- (F) LEFT LEVEL 2B NODES:
Three lymph nodes, no tumor.
- (G) SUPERIOR PHARYNGEAL MARGIN:
Squamous mucosa with mild dysplasia.
- (H) LARYNGECTOMY AND BILATERAL NECK NODE DISSECTION:
INVASIVE SQUAMOUS CARCINOMA INVADING PERINEURAL SPACES AND
LYMPHATICS MEASURING 1.5 CM IN THICKNESS AND INVOLVING THE RIGHT
PYRIFORM SINUS, SUPRAGLOTTIS, PERI-EPIGLOTTIC SPACE, AND
GLOTTIS.
Margins of resection free of tumor.
METASTATIC SQUAMOUS CARCINOMA IN 2 OF 5 LEFT CERVICAL LYMPH NODES.
METASTATIC SQUAMOUS CARCINOMA IN 2 OF 13 RIGHT CERVICAL LYMPH NODES
WITH EXTRACAPSULAR INVASION.
- (I) LEFT PROXIMAL JUGULAR VEIN BRANCH:
Blood vessel, no tumor present.

GROSS DESCRIPTION

- (A) RIGHT PYRIFORM - A single, unoriented, 0.6 x 0.3 x 0.3 cm soft tissue fragment. The specimen is submitted entirely in A for frozen section.
*FS/DX: ACANTHOTIC SQUAMOUS MUCOSA WITH MILD DYSPLASIA.
- (B) EPIGLOTTIS - Fragments of tan, irregular soft tissue and squamous mucosa aggregating to 1.0 x 1.0 x 0.6 cm. Entirely submitted in B1 and B2 for frozen section.
*FS/DX: INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
- (C) RIGHT EJ VEIN NODE - A single, 0.5 x 0.5 x 0.3 cm lymph node with attached scant fatty tissue. The lymph node is bisected and submitted entirely in C.

[page 2 of 2]
Received: [REDACTED]

Pathologist: [REDACTED]

Accession: [REDACTED]

Case type: Surgical History

(D) RIGHT JUGULAR BRANCH - The specimen is a 0.2 x 0.1 x 0.1 cm minute fragment of pink-tan soft tissue. The specimen is entirely submitted for frozen section.

SECTION CODE: [REDACTED]

*FS/DX: SQUAMOUS CARCINOMA IN FIBROCONNECTIVE TISSUE. [REDACTED]

(E) LEFT SPINAL ACCESSORY NODE - A single, 0.6 x 0.2 x 0.2 cm lymph node. The specimen is submitted entirely in E. [REDACTED]

(F) LEFT LEVEL 2B - A single, 0.5 x 0.4 x 0.4 cm lymph node and a separate 1.0 x 0.5 x 0.5 cm fragment of fatty tissue. The lymph node is bisected and submitted entirely in F1. The separate fatty tissue is bisected and submitted in F2. [REDACTED]

(G) INFERIOR PHARYNGEAL MARGIN - A 1.5 x 0.5 x 0.3 cm fragment of mucosa lined soft tissue entirely submitted for frozen section as G. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA WITH MILD DYSPLASIA. [REDACTED]

(H) LARYNGECTOMY AND BILATERAL NECK DISSECTION - A total laryngectomy and bilateral neck dissection, overall 7.0 x 8.0 x 4.0 cm. The right node dissection is approximately 13.0 x 4.0 x 2.0 cm and grossly involved and matted lymph nodes are identified. The left neck dissection is approximately 7.0 x 4.0 x 1.5 cm. No identifiable lymph node was found.

The laryngectomy specimen showed an ulcerated, light-tan and geographic lesion extending from the right pyriform sinus to the right supraglottic area crossing the midline and involving the entire epiglottic area measuring 4.5 x 2.5 x 1.5 cm. The tumor extends to the free space but does not extend to the margin of resection. The mucosal margin of resection also appears to be involved. Tumor extends submucosally under the supraglottic area on the left and abuts soft tissue margin of resection. The margin is submitted entirely from right to left sequentially under H1-H7, margin of resection on frozen; H8-H33, sequential sectioning from right to left including the supraglottic area and the free space. [REDACTED]

The fragment of left neck dissection (5 x 3 x 2 cm). The lymph nodes are dissected and with the largest measuring 1.0 cm in diameter. The lymph nodes are submitted entirely. A separate unoriented, fragment of right neck dissection is present. Lymph nodes are dissected with the largest measuring 3.5 cm in greatest dimension and containing apparent tumor metastasis.

SECTION CODE: H1-H7, mucosal margin of resection; H8-H33, tumor from left to right; H34-H36, lymph nodes of left neck dissection, submitted entirely (H34, one bisected node, H35 and H 36, two nodes per cassette); H37 and H38, representative sections of two large lymph nodes with apparent tumor metastasis, in right neck dissection; H39-H41, the remaining lymph nodes from right neck dissection (three nodes per cassette); H42, additional possible lymph nodes from right neck dissection. [REDACTED]

*FS/DX: NEGATIVE FOR INVASIVE SQUAMOUS CELL CARCINOMA. [REDACTED]

(I) LEFT PROXIMAL JUGULAR VEIN BRANCH - A fragment of soft tissue (0.2 x 0.1 x 0.1 cm). Ink is present on one aspect denoting "true margin". In toto in I for frozen section examination. [REDACTED]

*FS/DX: SEGMENT OF BLOOD VESSEL, NO TUMOR PRESENT. [REDACTED]

SNOMED CODES

M-80703 M-80706 T-24100 T-C4200

Source: NCI Genomic Data Commons file 7d9c2a3d-4bce-4c28-9e0c-86c66aa692b5 (TCGA-CV-7248.2C6F8710-356D-411C-83C0-F47807D8A900.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).